Surgical pathology report (de-identified scan), TCGA case TCGA-55-6987, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6987-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Patient
MRN
DOB
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name
Status

[REDACTED]

[REDACTED]

SEE REPORT

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. LEFT LOWER LOBE, LUNG, WEDGE BIOPSY, APC
- B. REMAINING LEFT LOWER LOBE OF LUNG
- C. AP WINDOW LYMPH NODE
- D. SUBCARINAL LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Left lower lobe lung mass

==== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

==== CLINICAL INFORMATION: =====

Left lower lobe lung mass, status post smoking history

==== INTRAOPERATIVE CONSULTATION: =====

APC DIAGNOSIS: "(Gross) pleural-based tumor, 2.0 cm from staple line; (smear) non-small cell carcinoma; 1.0 cm tumor and non-tumor tissue fragments for research" by [REDACTED]

==== GROSS DESCRIPTION: =====

- A/APC. The specimen consists of a wedge of lung, measuring 9.5 x 4.0 x 2.8 cm. The pleural surface reveals an irregular retracted area, measuring approximately 0.8 x 0.3 cm. A branching staple line, measuring 11 cm in length, is present. The specimen has been sectioned during pathology consultation. Sections show a well-defined subpleural mass, measuring 2.4 x 2.2 x 1.8 cm. The mass is composed of tan-white firm tissue. It is located 2.0 cm from the staple line. The remaining specimen shows tan-pink congested pulmonary parenchyma, with emphysematous changes. Representative sections are submitted in five cassettes as follows: cassette 1 - staple line; cassettes 2 through 4 - mass; cassette 5 - sections away from the mass.
- B. The specimen consists of the left lower lobe, measuring 19 x 14 x 5 cm and weighing 198 grams. The pleural surface is congested with three staple lines, measuring 5 cm, 6 cm, and 10 cm in length. The staple lines are inked black and the specimen is serially sectioned to reveal congested pulmonary parenchyma. No discrete mass is identified. The bronchial and vascular margins are unremarkable. Representative sections are submitted in six cassettes as follows: cassette 1 - bronchial margin; cassette 2 - vascular margin; cassette 3 - staple lines; cassettes 4 through 6 - random lung.
- C. The specimen consists of two portions of irregular tan-gray soft tissue,

[page 2 of 2]
[REDACTED]

Patient

MRN

DOB

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Status

Requested by: [REDACTED]

Surgical Report

DXSTIC X

measuring 1.0 x 0.3 x 0.2 cm and 1.4 x 1.2 x 0.3 cm. The specimen is submitted intact in one cassette.

D. The specimen consists of one portion of irregular tan-gray soft tissue, measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted intact in one cassette.

==== MICROSCOPIC DESCRIPTION: =====

A/APC. Five slides are examined. Slide 1 shows tissue from the region of the staple line. There is inflammation, but no tumor is identified. Sections of tumor appear on slides 2 through 5. This is non-small cell carcinoma, measuring about 2.2 cm in maximal dimension. The morphology is that of poorly-differentiated adenocarcinoma with predominantly solid areas, but occasional gland formation is identified. Foci consistent with lymphovascular invasion are present, seen on slide 3. Emphysematous lung is present on slide 5.

B. Six slides are examined. The bronchial margin shows no evidence of tumor involvement. The vascular margin is also free of tumor. Patchy emphysema is present in the remaining lung tissue.

C. One slide is examined. Sections of anthracotic lung tissue are present, without evidence of metastatic carcinoma.

D. One slide is examined. A section of anthracotic lymph node is identified. No evidence of metastatic tumor is present.

==== FINAL DIAGNOSIS: =====

A/APC & B. LEFT LOWER LOBE OF LUNG:

1. TUMOR TYPE: ADENOCARCINOMA, POORLY DIFFERENTIATED (G3), MEASURING ABOUT 2.2 CM IN MAXIMAL DIMENSION

2. FOCAL LYMPHOVASCULAR INVASION IS IDENTIFIED

3. CLEAR VASCULAR AND BRONCHIAL RESECTION MARGINS

4. REMAINING LUNG SHOWS MODERATE EMPHYSEMA

5. TNM CLASSIFICATION: pT1,N0,MX

C. LYMPH NODE, AP WINDOW: ANTHRACOSIS, NO TUMOR IDENTIFIED

D. LYMPH NODE, SUBCARINAL: ANTHRACOSIS, NO TUMOR IDENTIFIED

A-MALIGNANT

[REDACTED]

Source: NCI Genomic Data Commons file c52c0782-e1db-4573-b19e-cc1571ed2ac0 (TCGA-55-6987.345EB11F-9520-4463-8A84-07AEB26CE559.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).